Gene-level copy-number profile of tumor specimen TCGA-29-1695-01A from TCGA case TCGA-29-1695, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 62.7 years (22,895 days).
Specimen TCGA-29-1695-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.85c10346-60f7-45e9-9948-a150ef623db1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1695-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/89075e42-934b-4eba-8ac0-cb5cbe7b89c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 3,859; copy number 2: 17,749; copy number 3: 13,442; copy number 4: 13,971; copy number 5: 3,966; copy number 6: 3,150; copy number 7: 2,943; copy number 8: 291; copy number 9: 77; copy number 10: 137; copy number 11: 83; copy number 12: 79; copy number 13: 14; copy number 14: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1695-01A-01D-0559-01): tumor purity 0.66, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,582,552–117,027,039, 9 genes: RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr8:25,184,689–25,426,580, 5 genes (within-gene range 0–1): DOCK5, AC091185.2, MIR6876, GNRH1, AC091185.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,763 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5–6 (broad region; genes not listed).
- chr2:102,249,857–103,880,209, 23 genes, copy number 5: FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1, AC010881.1, AC011593.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2.
- chr2:114,114,679–115,940,291, 11 genes, copy number 5: AC010982.2, AC010982.1, SEPHS1P7, RNU2-41P, DPP10, DPP10-AS3, DPP10-AS2, AC093610.1, DPP10-AS1, RPSAP23, AC016721.1.
- chr2:163,152,251–163,736,012, 3 genes, copy number 6: RPL7P61, RNU6-627P, FIGN.
- chr2:171,999,943–174,043,880, 36 genes, copy number 5: METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1, CBY1P1, PPIAP66, AC013410.1, AC013410.2, AC106900.1, RPL5P7, SP3, AC016737.1, AC016737.2, LINC01960, RPSAP24.
- chr2:176,929,985–178,142,651, 35 genes, copy number 5: RNU6-187P, AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS, TTC30B, AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1, AC011998.2, API5P2, SDHDP5, RNU6-629P, CYCTP, AC011998.1, RBM45, RNU5E-9P.
- chr3:142,815,922–143,131,893, 11 genes, copy number 5: PCOLCE2, AC021074.1, AC021074.3, PAQR9, AC021074.2, PAQR9-AS1, U2SURP, AC026304.1, AC018450.2, CHST2, AC018450.1.
- chr3:145,824,257–155,944,020, 185 genes, copy number 5–9 (broad region; genes not listed).
- chr3:157,081,738–157,088,547, 1 gene, copy number 5 (within-gene range 2–5): LINC02029.
- chr3:157,259,742–158,106,420, 8 genes, copy number 5 (within-gene range 2–5): VEPH1, PTX3, SLC66A1L, AC084212.1, AC079943.2, RN7SKP46, AC079943.1, SHOX2.
- chr3:158,962,235–162,601,792, 45 genes, copy number 5–12: IQCJ-SCHIP1, IQCJ, MIR3919, AC063955.1, AC092943.2, AC092943.1, IQCJ-SCHIP1-AS1, RNU2-31P, SCHIP1, IL12A-AS1, IL12A, LINC01100, BRD7P2, C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1, TOMM22P6, AC128716.1.
- chr3:164,001,606–198,222,513, 638 genes, copy number 6–12 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5–6 (broad region; genes not listed).
- chr6:167,607–72,403,143, 1,629 genes, copy number 5–8 (broad region; genes not listed).
- chr6:123,803,865–125,264,407, 5 genes, copy number 5 (within-gene range 4–5): NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1.
- chr6:128,500,527–132,571,359, 56 genes, copy number 5: AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA, LAMA2, MESTP1, BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA, AL583803.1, SMLR1, EPB41L2, AKAP7, AL137222.1, RPL21P67, ARG1, MED23, ENPP3, RNU4-18P, OR2A4, CTAGE9, AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013, EEF1A1P36, MOXD1, STX7, RPL21P66, TAAR9, TAAR8, TAAR7P, TAAR6.
- chr6:157,700,387–170,738,536, 244 genes, copy number 6–8 (broad region; genes not listed).
- chr7:62,275,361–69,597,493, 220 genes, copy number 5 (broad region; genes not listed).
- chr7:70,837,738–159,233,377, 1,715 genes, copy number 5–6 (broad region; genes not listed).
- chr8:67,952,046–69,860,540, 24 genes, copy number 5: PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2.
- chr8:82,033,533–85,951,083, 49 genes, copy number 5 (within-gene range 4–5): AC060765.2, LINC02839, HNRNPA1P4, AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849.
- chr8:120,052,180–120,056,201, 1 gene, copy number 6: AC091563.1.
- chr11:120,867,933–122,027,667, 16 genes, copy number 5 (within-gene range 4–5): AP004147.1, HMGB1P42, TBCEL, TBCEL-TECTA, TECTA, AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1, AP001977.1, AP001924.1, RNU6-256P, AP001924.2.
- chr11:122,099,757–122,152,308, 4 genes, copy number 5: MIR125B1, BLID, MIRLET7A2, MIR100.
- chr12:66,767–27,972,733, 722 genes, copy number 7–10 (broad region; genes not listed).
- chr13:81,689,911–84,069,408, 12 genes, copy number 5: PTMAP5, AL445255.1, GYG1P2, AL512782.1, RNU6-67P, AL353688.1, SLITRK1, AL355481.1, VENTXP2, AL590681.1, UBE2D3P4, AL445604.1.
- chr15:71,792,638–72,900,260, 41 genes, copy number 5: NR2E3, AC104938.1, MYO9A, RNA5SP399, AC022872.1, EIF5A2P1, RNU2-65P, SENP8, AC020779.1, AC020779.2, GRAMD2A, PKM, PARP6, AC009690.3, AC009690.2, CELF6, AC009690.1, HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1, AC103874.1, NPM1P42.
- chr19:8,322,584–9,675,100, 64 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:10,817,426–12,974,762, 160 genes, copy number 6 (broad region; genes not listed).
- chr19:13,013,662–13,014,511, 1 gene, copy number 6: AC138474.1.
- chr19:15,159,038–20,127,076, 276 genes, copy number 5 (broad region; genes not listed).
- chr19:20,125,044–20,200,488, 5 genes, copy number 5: AC011447.1, AC011447.2, BNIP3P15, ZNF486, BNIP3P16.
- chr19:22,925,377–39,435,949, 475 genes, copy number 5–14 (broad region; genes not listed).
- chr20:87,250–34,347,785, 692 genes, copy number 6–8 (broad region; genes not listed).
- chr20:34,384,165–34,442,025, 3 genes, copy number 6: Y_RNA, CDC42P1, ITCH-AS1.
- chr20:37,693,955–38,772,520, 39 genes, copy number 5 (within-gene range 4–5): CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173.

Autosomal genes at a single copy (total copy number 1): 1,451. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
